Somatic mutation profile of tumor specimen C3L-04537-01 (aliquot CPT0264330006) from CPTAC case C3L-04537, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 51.4 years (18,762 days).
Specimen C3L-04537-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f102fac5-bf39-40e9-83b3-70dd9fa3f3c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04537-31 (Blood Derived Normal), aliquot CPT0265790002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62ab3794-0a5e-434f-b9b5-ba688e8411c8

The open-access MAF lists 68 somatic variants for this specimen: 44 protein-altering or splice-affecting, 20 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 20, Nonsense Mutation 2, Frame Shift Del 2, Splice Site 2, Frame Shift Ins 1, 3'UTR 1, 5'UTR 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF25 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 70/226 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1278195704; called by muse, mutect2, varscan2
- ATP6V1B1 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 147/535 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs555708728, COSV52270451; called by muse, mutect2, varscan2
- C3 | c.3400C>T p.R1134W | Missense Mutation (SNP) | VAF 103/365 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs138900723; called by muse, mutect2, varscan2
- C8orf34 | c.647C>T p.T216I | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV61385344; called by muse, mutect2
- CAPN13 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs376824805; called by muse, mutect2, varscan2
- CTAGE1 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.078); catalogued as COSV66942991; called by muse, mutect2, varscan2
- EPHA8 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 53/181 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs760177071; called by muse, mutect2, varscan2
- FGD5 | c.1111G>A p.G371S | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.197); catalogued as COSV53254916; called by muse, mutect2, varscan2
- GRIN2A | c.2894C>T p.T965I | Missense Mutation (SNP) | VAF 125/426 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.196); catalogued as rs886042323; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITGAD | c.2045G>A p.R682H | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs141968317, COSV101210591; called by muse, mutect2, varscan2
- KANSL1L | c.78G>T p.K26N | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.691); catalogued as COSV99911080; called by muse, mutect2, varscan2
- KIF23 | c.1097C>T p.T366M | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs377663038; called by muse, mutect2, varscan2
- MOCOS | c.1129G>A p.D377N | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.141); catalogued as rs1415461432, COSV54341736; called by muse, mutect2
- MPO | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 118/455 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs375834447; called by muse, mutect2, varscan2
- MUC12 | c.896C>T p.T299M (on ENST00000379442; = p.T156M on NM_001164462.1) | Missense Mutation (SNP) | VAF 154/683 reads (23%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.551); catalogued as rs370911866; called by muse, mutect2, varscan2
- NASP | c.478dup p.T160Nfs*10 | Frame Shift Ins (INS) | VAF 30/93 reads (32%) | catalogued as rs1212178296; called by mutect2, varscan2
- NWD1 | c.3541G>A p.G1181R | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs199771656; called by muse, mutect2, varscan2
- OR52K1 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs376724184; called by muse, mutect2
- P2RX2 | c.1291G>A p.E431K (on ENST00000343948 / NM_170683.4; = p.E333K on NM_012226.5) | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.023); catalogued as rs755760731; called by muse, mutect2, varscan2
- PCDHA10 | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 57/494 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.298); catalogued as COSV100253389; called by muse, mutect2, varscan2
- PCDHA12 | c.1688C>T p.P563L | Missense Mutation (SNP) | VAF 197/680 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as rs782531082, COSV100255922; called by muse, mutect2, varscan2
- PDCD11 | c.3598G>A p.G1200S | Missense Mutation (SNP) | VAF 55/106 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as COSV63935072; called by muse, mutect2, varscan2
- PDGFRA | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 432/1924 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV57264188; called by muse, mutect2, varscan2
- PEX19 | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 154/553 reads (28%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.099); catalogued as COSV54099669; called by muse, mutect2, varscan2
- PRPF19 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 74/203 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57127307; called by muse, mutect2, varscan2
- SPDYE4 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 85/211 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs886348041; called by muse, mutect2, varscan2
- SUPT5H | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1267176767; called by muse, mutect2, varscan2
- TAT | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 132/519 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as rs371975183; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP63 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 113/406 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs762371837, CM118065, COSV53197105; called by muse, mutect2, varscan2
- ZDHHC7 | c.890C>T p.T297M | Missense Mutation (SNP) | VAF 136/424 reads (32%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs143906848; called by muse, mutect2, varscan2
- ARNT | c.1267_1268del p.L423Vfs*9 | Frame Shift Del (DEL) | VAF 7/55 reads (13%) | called by mutect2, pindel, varscan2
- C4orf17 | c.546+2dup p.X182_splice | Splice Site (INS) | VAF 7/33 reads (21%) | called by mutect2, pindel, varscan2
- CD302 | c.178+2T>C p.X60_splice | Splice Site (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2
- COL3A1 | c.1907G>A p.G636D | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- FREM3 | c.1003G>A p.V335I | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GLE1 | c.329A>G p.D110G | Missense Mutation (SNP) | VAF 70/236 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KCNH5 | c.2350C>T p.L784F | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PHF21B | c.1285G>T p.E429* | Nonsense Mutation (SNP) | VAF 54/188 reads (29%) | called by muse, mutect2, varscan2
- PLEKHM2 | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 40/104 reads (38%) | called by muse, mutect2
- PTEN | c.742_746del p.P248Vfs*3 | Frame Shift Del (DEL) | VAF 37/86 reads (43%) | called by mutect2, pindel, varscan2
- SCAF1 | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- SUGT1 | c.984G>C p.M328I (on ENST00000343788 / NM_001130912.3; = p.M296I on NM_006704.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMEM30B | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 67/186 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- TRPM6 | c.335T>C p.I112T | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.801C>G p.L267= | Silent (SNP) | VAF 81/305 reads (27%) | called by muse, mutect2, varscan2
- ACE | c.1056C>T p.A352= | Silent (SNP) | VAF 57/224 reads (25%) | catalogued as rs369739909; called by muse, mutect2, varscan2
- ACOX1 | c.975A>G p.Q325= | Silent (SNP) | VAF 119/286 reads (42%) | called by muse, mutect2, varscan2
- APC2 | c.5136C>A p.S1712= | Silent (SNP) | VAF 27/135 reads (20%) | called by muse, mutect2, varscan2
- EPHB4 | c.888C>G p.T296= | Silent (SNP) | VAF 14/332 reads (4%) | called by muse, mutect2
- GSTA5 | c.468T>G p.A156= | Silent (SNP) | VAF 13/310 reads (4%) | called by muse, mutect2
- IMPG1 | c.1269C>T p.D423= | Silent (SNP) | VAF 42/171 reads (25%) | catalogued as rs758038128, COSV64054519, COSV64057625; called by muse, mutect2, varscan2
- LRRFIP2 | c.663T>C p.S221= | Silent (SNP) | VAF 24/94 reads (26%) | called by muse, mutect2, varscan2
- MUC4 | c.7716T>A p.G2572= | Silent (SNP) | VAF 83/540 reads (15%) | catalogued as rs200842185; called by muse, mutect2, varscan2
- NPAT | c.801A>T p.I267= | Silent (SNP) | VAF 18/69 reads (26%) | called by muse, mutect2, varscan2
- OR2L2 | c.423G>T p.V141= | Silent (SNP) | VAF 14/175 reads (8%) | called by muse, mutect2
- PCDHGA8 | c.1935C>T p.A645= | Silent (SNP) | VAF 124/311 reads (40%) | called by muse, mutect2, varscan2
- PDGFRA | c.1614G>C p.V538= | Silent (SNP) | VAF 132/4939 reads (3%) | called by muse, mutect2
- PTPRB | c.5136C>T p.D1712= | Silent (SNP) | VAF 32/126 reads (25%) | catalogued as rs1305673646; called by muse, mutect2, varscan2
- RABGAP1L | c.1140C>T p.N380= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as rs749431855, COSV52315008; called by muse, mutect2, varscan2
- TBX18 | c.1353G>A p.P451= | Silent (SNP) | VAF 52/136 reads (38%) | catalogued as rs774472628, COSV63736776; called by muse, mutect2, varscan2
- TMEM132D | c.777G>A p.E259= | Silent (SNP) | VAF 127/411 reads (31%) | catalogued as rs150219380; called by muse, mutect2, varscan2
- TTC16 | c.1584C>T p.H528= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs749065817, COSV60162398; called by muse, mutect2
- USH2A | c.14961G>A p.A4987= | Silent (SNP) | VAF 72/220 reads (33%) | catalogued as rs568581229, COSV100231269, COSV100244664; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF135 | c.765G>A p.S255= (on ENST00000313434 / NM_001289401.2; = p.S267= on NM_003436.4) | Silent (SNP) | VAF 96/380 reads (25%) | catalogued as rs759974514; called by muse, mutect2, varscan2
- AC235097.1 | n.221T>A | RNA (SNP) | VAF 53/100 reads (53%) | called by muse, mutect2, varscan2
- CACNA2D1 | c.-17G>T | 5'UTR (SNP) | VAF 45/614 reads (7%) | called by muse, mutect2
- COQ9 | c.379-32C>T | Intron (SNP) | VAF 73/252 reads (29%) | catalogued as rs201630061; called by muse, mutect2, varscan2
- FAM78B | c.*576G>A | 3'UTR (SNP) | VAF 30/90 reads (33%) | catalogued as rs745591964; called by muse, mutect2, varscan2
